Surgical pathology report (de-identified scan), TCGA case TCGA-22-4596, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-4596-01A (Primary Tumor).

Surgical Pathology

TISSUE DESCRIPTION:

Left upper lobe lung wedge excision (11 x 8 x 3 cm), left upper lobe lung (105 grams), inferior mediastinal (subcarinal, paraesophageal, left inferior pulmonary ligament), aortic (aortopulmonary, anterior mediastinal) and N1 (left interlobar) lymph nodes

DIAGNOSIS:

Lung, left upper lobe, wedge excision: Grade 3 (of 4) squamous cell carcinoma, forms a 2.3 x 2 x 1.8 cm mass abutting but not directly invading the pleura.

Lung, left upper lobe, lobectomy: Benign lung parenchyma with multiple (3) intrapulmonary peribronchial lymph nodes are present. No residual tumor is seen. The bronchial margin is negative.

Lymph nodes, inferior mediastinal, aortic and N1, excision: Multiple inferior mediastinal (1 subcarinal, 2 paraesophageal, 2 left inferior pulmonary ligament), aortic (2 anterior mediastinal) and N1 (2 left interlobar) lymph nodes are negative for tumor. Tissue submitted as aortopulmonary lymph node shows fibrovascular tissue; no lymphoid tissue identified.

Source: NCI Genomic Data Commons file 7805c492-788d-44ab-98c9-d06517374e3c (TCGA-22-4596.FD87FACC-8690-4F1A-BF75-1E6D2C1E8882.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).